Somatic mutation profile of tumor specimen TARGET-30-PARKZF-01A (aliquot TARGET-30-PARKZF-01A-01D) from TARGET case TARGET-30-PARKZF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-30-PARKZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 040306cf-8685-46b9-b0c7-2a04ba6d38da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARKZF-10A (Blood Derived Normal), aliquot TARGET-30-PARKZF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0736c807-56e9-4333-ae72-5bf2acf028f1

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC158 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); catalogued as rs376849991; called by muse, mutect2
- KANSL1 | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52270820; called by muse, mutect2, varscan2
- MMP1 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59510942; called by muse, mutect2, varscan2
- NDST3 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56623369; called by muse, mutect2, varscan2
- OXR1 | c.1201C>T p.H401Y (on ENST00000442977 / NM_001198532.1; = p.H400Y on NM_018002.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV56332562; called by muse, mutect2, varscan2
- RPTN | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60166432, COSV60168091; called by muse, mutect2, varscan2
- UTP20 | c.6445G>T p.E2149* | Nonsense Mutation (SNP) | VAF 49/186 reads (26%) | catalogued as COSV55380777; called by muse, mutect2, varscan2
- CTDSPL2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | called by muse, varscan2
- ENAH | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF835 | c.663_676del p.Y222Vfs*21 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- RASGRP3 | c.1620G>T p.L540= (on ENST00000402538 / NM_001349975.2; = p.L539= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV67823268; called by muse, mutect2, varscan2
- RHOC | c.225G>A p.P75= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs764236081, COSV53517311, COSV99588196; called by muse, mutect2, varscan2
